Gene-level copy-number profile of tumor specimen TCGA-FD-A6TF-01A from TCGA case TCGA-FD-A6TF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 80.3 years (29,317 days).
Specimen TCGA-FD-A6TF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ab0036fc-e109-4ded-96db-6f6dcd0c15ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aacd89cc-40b3-463e-b80f-526c8f08d0cc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 544; copy number 2: 14,795; copy number 3: 19,186; copy number 4: 12,303; copy number 5: 8,470; copy number 6: 2,918; copy number 7: 626; copy number 8: 649; copy number 9: 42; copy number 10: 53; copy number 11: 130; copy number 12: 2; copy number 13: 31; copy number 15: 4; copy number 18: 6; copy number 21: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TF-01A-52D-A32A-01): tumor purity 0.31, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:30,384,511–30,572,256, 2 genes (within-gene range 0–2): RBPMS, AC102945.2.
- chr10:109,184,934–110,008,381, 10 genes: RNU5B-6P, RNU6-839P, PHB2P1, BTF3P15, AL390123.1, XIAPP1, RPL21P91, XPNPEP1, RNU4-5P, ADD3-AS1.
- chr12:18,080,869–18,320,107, 1 gene: RERGL.
- chr14:67,727,374–67,816,590, 1 gene (within-gene range 0–2): ZFYVE26.
- chr14:67,751,228–68,730,218, 8 genes (within-gene range 0–2): RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,570 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:85,799,987–90,261,708, 41 genes, copy number 11–21: CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr6:66,710,242–68,329,899, 15 genes, copy number 7: AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549.
- chr7:127,997,597–128,731,743, 38 genes, copy number 11 (within-gene range 5–11): SND1-IT1, LRRC4, MIR593, MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P, AC010655.4, HILPDA, AC010655.2, AC010655.3, METTL2B, Metazoa_SRP, AC090114.2, AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3, FAM71F2, AC018638.6, IMP3P2, RNA5SP242, RNA5SP243, FAM71F1.
- chr9:4,299,390–10,612,723, 93 genes, copy number 10–18 (within-gene range 3–18) (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 8–11 (broad region; genes not listed).
- chr12:990,509–1,495,933, 1 gene, copy number 7 (within-gene range 5–7): ERC1.
- chr12:1,380,060–6,160,719, 114 genes, copy number 7–8 (broad region; genes not listed).
- chr17:67,611,277–68,601,367, 37 genes, copy number 8: AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1.
- chr18:47,390–2,916,003, 62 genes, copy number 7 (broad region; genes not listed).
- chr18:5,289,019–15,330,282, 265 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:36,034,984–40,765,389, 229 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 544. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
